Somatic mutation profile of cancer-model specimen HCM-CSHL-0654-C26-85M (3D Organoid, passage 7; aliquot HCM-CSHL-0654-C26-85M-01D-A82H-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0654-C26, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Carcinoma, NOS; Tissue or organ of origin: Unknown primary site; Tumor grade: G3; Age at diagnosis: 70.6 years (25,800 days).
Specimen HCM-CSHL-0654-C26-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 7.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) faef085d-566c-43ea-b735-5a573f53954f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0654-C26-10A (Blood Derived Normal), aliquot HCM-CSHL-0654-C26-10A-01D-A82H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/59d1e76a-5e63-489e-b326-3752782a1826

The open-access MAF lists 138 somatic variants for this specimen: 105 protein-altering or splice-affecting, 28 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 94, Silent 28, Nonsense Mutation 4, Frame Shift Del 3, Frame Shift Ins 2, Intron 2, Splice Site 2, 3'UTR 1, 5'Flank 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 445/446 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACIN1 | c.4010G>A p.R1337Q | Missense Mutation (SNP) | VAF 153/476 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.273); catalogued as COSV52982991; called by muse, mutect2, varscan2
- ACTL9 | c.1187G>T p.C396F | Missense Mutation (SNP) | VAF 174/554 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.986); catalogued as COSV61004765; called by muse, mutect2, varscan2
- ADGRA2 | c.290C>T p.T97M | Missense Mutation (SNP) | VAF 245/392 reads (63%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs763577512, COSV59442898; called by muse, mutect2, varscan2
- ADGRD1 | c.1816G>A p.A606T | Missense Mutation (SNP) | VAF 168/566 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.553); catalogued as rs1394144734, COSV55446523; called by muse, mutect2, varscan2
- ATP1A2 | c.916G>A p.V306M | Missense Mutation (SNP) | VAF 176/582 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as rs748881406; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BANF2 | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 260/415 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1317561867, COSV101617993; called by muse, mutect2, varscan2
- BMPER | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 238/526 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.073); catalogued as rs746885660; called by muse, mutect2, varscan2
- BRIP1 | c.2233G>A p.A745T | Missense Mutation (SNP) | VAF 180/180 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as rs587780235, CM1210625, COSV52004661; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCR2 | c.41A>G p.N14S | Missense Mutation (SNP) | VAF 181/323 reads (56%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1283636260; called by muse, mutect2, varscan2
- CCR7 | c.928G>A p.V310I | Missense Mutation (SNP) | VAF 176/578 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.078); catalogued as rs773362430; called by muse, varscan2
- CES1 | c.11G>T p.R4L | Missense Mutation (SNP) | VAF 277/279 reads (99%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs111604615; called by muse, varscan2
- CHRD | c.2369G>A p.R790Q | Missense Mutation (SNP) | VAF 148/320 reads (46%) | SIFT tolerated (0.56); PolyPhen benign (0.28); catalogued as rs771365613, COSV52608775; called by muse, mutect2, varscan2
- CHRDL1 | c.327C>A p.C109* (on ENST00000372045; = p.C115* on NM_145234.4) | Nonsense Mutation (SNP) | VAF 456/456 reads (100%) | catalogued as COSV99488868; called by muse, mutect2, varscan2
- CHRM2 | c.920C>G p.T307R | Missense Mutation (SNP) | VAF 219/345 reads (63%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as COSV100280591; called by muse, mutect2, varscan2
- CSMD3 | c.2422C>T p.R808* (on ENST00000297405 / NM_001363185.1; = p.R704* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 118/392 reads (30%) | catalogued as COSV52172375; called by muse, mutect2, varscan2
- CXCL9 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1375851280, COSV53578486; called by muse, mutect2, varscan2
- CYP11B1 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 123/429 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as rs764251434, CM1210436, COSV52830527; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CYP2B6 | c.1328G>A p.R443H | Missense Mutation (SNP) | VAF 242/392 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as rs374099483; called by muse, mutect2, varscan2
- DDR1 | c.2584C>T p.R862W (on ENST00000324771; = p.R825W on NM_001954.4) | Missense Mutation (SNP) | VAF 406/920 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757977513, COSV61326143; called by muse, varscan2
- DGKG | c.442G>A p.V148I | Missense Mutation (SNP) | VAF 185/418 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.018); catalogued as rs368444168, COSV53975826; called by muse, mutect2
- DSCAM | c.5418T>G p.S1806R | Missense Mutation (SNP) | VAF 146/351 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1396609521, COSV101261249, COSV68020569; called by muse, mutect2, varscan2
- DYNC1I1 | c.773G>A p.R258Q | Missense Mutation (SNP) | VAF 181/276 reads (66%) | SIFT tolerated (0.64); PolyPhen benign (0.018); catalogued as rs756345512, COSV61474207; called by muse, mutect2, varscan2
- EVC | c.1979C>T p.T660M | Missense Mutation (SNP) | VAF 239/507 reads (47%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.799); catalogued as rs550100215, COSV53828779; called by muse, mutect2, varscan2
- F8 | c.3986G>A p.R1329H | Missense Mutation (SNP) | VAF 429/429 reads (100%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs782767347, CM062655, COSV64276561; called by muse, mutect2, varscan2
- FER1L6 | c.2920G>T p.D974Y | Missense Mutation (SNP) | VAF 7314/7604 reads (96%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV67549139; called by muse, mutect2, varscan2
- FMN2 | c.2200C>T p.R734W | Missense Mutation (SNP) | VAF 382/755 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs145706266, COSV60434698; called by muse, mutect2, varscan2
- FREM3 | c.3002G>T p.G1001V | Missense Mutation (SNP) | VAF 139/303 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs913177045; called by muse, mutect2, varscan2
- FRMPD4 | c.1870A>C p.S624R | Missense Mutation (SNP) | VAF 233/715 reads (33%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.031); catalogued as COSV101043163; called by muse, mutect2, varscan2
- FTCD | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 163/366 reads (45%) | SIFT tolerated (0.79); PolyPhen benign (0.01); catalogued as rs761284163, COSV52428151; called by muse, mutect2, varscan2
- GPR17 | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 283/600 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs746206534; called by muse, mutect2, varscan2
- HYAL3 | c.1109G>A p.R370Q | Missense Mutation (SNP) | VAF 26/820 reads (3%) | SIFT tolerated (0.43); PolyPhen benign (0.009); catalogued as rs141011866; called by muse, mutect2
- IFFO2 | c.1522C>T p.R508C | Missense Mutation (SNP) | VAF 76/254 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); catalogued as rs566982605; called by muse, mutect2, varscan2
- IKBKB | c.352C>T p.R118W | Missense Mutation (SNP) | VAF 315/490 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs201303042; called by muse, mutect2, varscan2
- KCNB1 | c.112G>A p.G38R | Missense Mutation (SNP) | VAF 563/812 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65570416; called by muse, mutect2, varscan2
- KCNT2 | c.695C>A p.S232Y | Missense Mutation (SNP) | VAF 111/569 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54062032; called by muse, mutect2, varscan2
- LRP1 | c.844G>A p.V282M | Missense Mutation (SNP) | VAF 181/275 reads (66%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as rs937133751, COSV54505729; called by muse, mutect2, varscan2
- MED12 | c.3896C>T p.S1299F | Missense Mutation (SNP) | VAF 176/177 reads (99%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as COSV61336539; called by muse, mutect2, varscan2
- MTOR | c.5533G>A p.E1845K | Missense Mutation (SNP) | VAF 97/973 reads (10%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.974); catalogued as rs762176419, COSV63871869; called by muse, mutect2
- NF1 | c.6755T>G p.F2252C (on ENST00000358273 / NM_001042492.3; = p.F2231C on NM_000267.3) | Missense Mutation (SNP) | VAF 266/266 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as CD1512869; called by muse, varscan2
- NIPAL4 | c.1324G>A p.V442I | Missense Mutation (SNP) | VAF 116/117 reads (99%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs780925737, COSV57428964; called by muse, mutect2, varscan2
- OTUD6A | c.41G>A p.R14H | Missense Mutation (SNP) | VAF 238/238 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100611112; called by muse, mutect2, varscan2
- PADI4 | c.1813G>A p.V605I | Missense Mutation (SNP) | VAF 124/391 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs752032759, COSV64923993; called by muse, mutect2, varscan2
- PANX3 | c.86G>A p.R29H | Missense Mutation (SNP) | VAF 381/579 reads (66%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs766598167, COSV52513815, COSV99421153; called by muse, mutect2, varscan2
- PDGFD | c.1109G>A p.R370Q | Missense Mutation (SNP) | VAF 256/256 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs766800369, COSV56371243, COSV56394791; called by muse, mutect2, varscan2
- PERM1 | c.1888C>T p.R630W | Missense Mutation (SNP) | VAF 253/729 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.764); catalogued as rs930930835; called by muse, mutect2, varscan2
- PNPLA1 | c.319G>C p.V107L (on ENST00000394571 / NM_001374623.1; = p.V12L on NM_173676.2) | Missense Mutation (SNP) | VAF 156/330 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as rs1488395690; called by muse, mutect2, varscan2
- PRAMEF14 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 66/546 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as rs752175196, COSV100577268; called by muse, mutect2, varscan2
- PROSER2 | c.700C>T p.R234C | Missense Mutation (SNP) | VAF 655/1020 reads (64%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); catalogued as rs1034555580; called by muse, mutect2, varscan2
- RASGRF1 | c.1399C>T p.P467S | Missense Mutation (SNP) | VAF 97/343 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.426); catalogued as COSV69180374; called by muse, mutect2, varscan2
- SCML4 | c.871C>T p.R291C | Missense Mutation (SNP) | VAF 409/612 reads (67%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.719); catalogued as rs773253589, COSV64637581; called by muse, mutect2, varscan2
- SSC5D | c.581G>A p.R194H | Missense Mutation (SNP) | VAF 179/271 reads (66%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs941672507, COSV52702986; called by muse, mutect2, varscan2
- STC2 | c.343C>T p.R115W | Missense Mutation (SNP) | VAF 195/367 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54179778; called by muse, mutect2, varscan2
- TENM2 | c.6353G>A p.R2118H (on ENST00000518659 / NM_001122679.2; = p.R1879H on NM_001080428.3) | Missense Mutation (SNP) | VAF 144/311 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.818); catalogued as rs778807457, COSV101319504; called by muse, mutect2, varscan2
- TSSK1B | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 170/385 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs745469147, COSV101181041; called by muse, mutect2, varscan2
- WDPCP | c.74A>G p.Q25R | Missense Mutation (SNP) | VAF 159/334 reads (48%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.328); catalogued as rs1197970797; called by muse, mutect2, varscan2
- XRCC6 | c.1637-1G>C p.X546_splice | Splice Site (SNP) | VAF 106/273 reads (39%) | catalogued as COSV63753686; called by muse, mutect2, varscan2
- ZBTB46 | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 167/476 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1204910445; called by muse, mutect2, varscan2
- ADSS2 | c.473dup p.N158Kfs*30 | Frame Shift Ins (INS) | VAF 124/302 reads (41%) | called by mutect2, pindel, varscan2
- AFDN | c.106-1G>A p.X36_splice | Splice Site (SNP) | VAF 197/198 reads (99%) | called by muse, mutect2, varscan2
- AGRN | c.238G>A p.V80M | Missense Mutation (SNP) | VAF 122/444 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- ANO3 | c.1173G>T p.K391N | Missense Mutation (SNP) | VAF 98/205 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ARID3B | c.1496_1497del p.V499Gfs*82 (on ENST00000622429 / NM_001307939.1; = p.V498Gfs*82 on NM_006465.4) | Frame Shift Del (DEL) | VAF 146/535 reads (27%) | called by pindel, varscan2
- AVP | c.332T>C p.V111A | Missense Mutation (SNP) | VAF 192/764 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- BMP8A | c.311T>C p.L104P | Missense Mutation (SNP) | VAF 19/636 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); called by muse, mutect2
- C12orf40 | c.1917G>T p.K639N | Missense Mutation (SNP) | VAF 113/200 reads (57%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CHML | c.1448A>C p.E483A | Missense Mutation (SNP) | VAF 224/498 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- CYP2U1 | c.142T>A p.W48R | Missense Mutation (SNP) | VAF 306/593 reads (52%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- DAPK3 | c.1031G>A p.R344H | Missense Mutation (SNP) | VAF 269/896 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, varscan2
- FREM2 | c.7830T>G p.Y2610* | Nonsense Mutation (SNP) | VAF 125/286 reads (44%) | called by muse, mutect2, varscan2
- FRMPD1 | c.3520C>T p.P1174S | Missense Mutation (SNP) | VAF 179/357 reads (50%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GPR88 | c.1051C>A p.L351M | Missense Mutation (SNP) | VAF 252/777 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- HOXA13 | c.151_172del p.A51Sfs*33 | Frame Shift Del (DEL) | VAF 178/779 reads (23%) | called by mutect2, pindel, varscan2
- IRAK1BP1 | c.152G>T p.R51L | Missense Mutation (SNP) | VAF 231/693 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KCTD8 | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 238/510 reads (47%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- KLKB1 | c.1795G>C p.G599R | Missense Mutation (SNP) | VAF 186/391 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MAP11 | c.485C>G p.P162R | Missense Mutation (SNP) | VAF 108/340 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MEGF6 | c.1690T>G p.C564G | Missense Mutation (SNP) | VAF 147/465 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MUC2 | c.282_300del p.G95Pfs*31 | Frame Shift Del (DEL) | VAF 248/255 reads (97%) | called by mutect2, pindel, varscan2
- NRG1 | c.1789G>T p.A597S (on ENST00000405005 / NM_013964.5; = p.A602S on NM_013956.5) | Missense Mutation (SNP) | VAF 163/550 reads (30%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- P4HB | c.1273A>G p.M425V | Missense Mutation (SNP) | VAF 177/514 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- PLEKHS1 | c.1325C>T p.T442I | Missense Mutation (SNP) | VAF 197/197 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PLXNA1 | c.991G>A p.A331T | Missense Mutation (SNP) | VAF 173/376 reads (46%) | SIFT tolerated (0.49); PolyPhen benign (0.232); called by muse, varscan2
- PYHIN1 | c.1256G>T p.S419I | Missense Mutation (SNP) | VAF 165/556 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- RIOK3 | c.307T>A p.F103I | Missense Mutation (SNP) | VAF 100/292 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SCN2A | c.1502T>A p.L501Q | Missense Mutation (SNP) | VAF 106/201 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SHANK3 | c.4627C>T p.R1543C | Missense Mutation (SNP) | VAF 174/576 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, varscan2
- SLC20A2 | c.1661G>A p.R554K | Missense Mutation (SNP) | VAF 152/465 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- SLC27A3 | c.508dup p.C170Lfs*51 (on ENST00000271857; = p.C42Lfs*51 on NM_024330.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 296/1021 reads (29%) | called by mutect2, pindel, varscan2
- SLCO1C1 | c.476G>C p.S159T | Missense Mutation (SNP) | VAF 25/214 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2
- SNRPB2 | c.157T>A p.F53I | Missense Mutation (SNP) | VAF 138/454 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- STC2 | c.147T>A p.N49K | Missense Mutation (SNP) | VAF 178/368 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- SYNE1 | c.11876T>C p.I3959T | Missense Mutation (SNP) | VAF 368/368 reads (100%) | SIFT tolerated (0.41); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- TFPI2 | c.421G>C p.D141H | Missense Mutation (SNP) | VAF 241/374 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TRHDE | c.833G>C p.C278S | Missense Mutation (SNP) | VAF 220/345 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRIM49B | c.850C>G p.Q284E | Missense Mutation (SNP) | VAF 33/197 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRPM3 | c.2623G>A p.V875M (on ENST00000357533 / NM_001366142.2; = p.V718M on NM_020952.6) | Missense Mutation (SNP) | VAF 129/256 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- UBR1 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- USP53 | c.2245T>G p.L749V | Missense Mutation (SNP) | VAF 77/148 reads (52%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- VPS33B | c.744G>C p.E248D | Missense Mutation (SNP) | VAF 121/420 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- WDR48 | c.314A>C p.H105P | Missense Mutation (SNP) | VAF 45/196 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- WIPF3 | c.1112G>A p.G371E | Missense Mutation (SNP) | VAF 125/569 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- WWP1 | c.1259T>C p.F420S | Missense Mutation (SNP) | VAF 163/525 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- XPO7 | c.215C>G p.S72* | Nonsense Mutation (SNP) | VAF 107/256 reads (42%) | called by muse, mutect2, varscan2
- ZNF431 | c.1473A>C p.K491N | Missense Mutation (SNP) | VAF 49/151 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- ABCA2 | c.5070G>A p.P1690= (on ENST00000614293; = p.P1660= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 213/776 reads (27%) | catalogued as rs768594701, COSV55800424; called by muse, mutect2, varscan2
- ADPRHL1 | c.1197C>T p.R399= | Silent (SNP) | VAF 274/902 reads (30%) | catalogued as rs969405629; called by muse, mutect2, varscan2
- BHLHE22 | c.201G>A p.P67= | Silent (SNP) | VAF 226/748 reads (30%) | catalogued as rs531148752, COSV100417581; called by muse, mutect2, varscan2
- C1QL2 | c.582G>A p.K194= | Silent (SNP) | VAF 171/347 reads (49%) | catalogued as COSV55607482; called by muse, mutect2, varscan2
- CCDC149 | c.1467G>A p.T489= (on ENST00000635206 / NM_001330643.2; = p.T478= on NM_173463.5) | Silent (SNP) | VAF 156/351 reads (44%) | catalogued as rs774261219; called by muse, mutect2, varscan2
- DRD5 | c.738G>A p.T246= | Silent (SNP) | VAF 154/321 reads (48%) | catalogued as COSV58580737; called by muse, mutect2, varscan2
- FBXO43 | c.1305G>A p.K435= | Silent (SNP) | VAF 138/365 reads (38%) | catalogued as COSV104435722; called by muse, mutect2, varscan2
- FDPS | c.1014T>C p.V338= | Silent (SNP) | VAF 319/468 reads (68%) | called by muse, mutect2, varscan2
- FIGNL2 | c.867C>T p.P289= | Silent (SNP) | VAF 607/972 reads (62%) | catalogued as rs781645879; called by muse, mutect2, varscan2
- FREM2 | c.3207C>A p.I1069= | Silent (SNP) | VAF 104/211 reads (49%) | catalogued as COSV54852503; called by muse, mutect2, varscan2
- GRIN3B | c.555C>T p.G185= | Silent (SNP) | VAF 333/948 reads (35%) | catalogued as rs748400627; called by muse, mutect2, varscan2
- H4C4 | c.120C>T p.R40= | Silent (SNP) | VAF 155/470 reads (33%) | catalogued as rs756481227; called by muse, mutect2, varscan2
- HEMK1 | c.180C>T p.A60= | Silent (SNP) | VAF 150/428 reads (35%) | called by muse, mutect2, varscan2
- HFM1 | c.3861T>C p.D1287= | Silent (SNP) | VAF 7/39 reads (18%) | called by muse, mutect2, varscan2
- JAK3 | c.2949C>G p.V983= | Silent (SNP) | VAF 216/716 reads (30%) | called by muse, mutect2, varscan2
- MECOM | c.69C>T p.C23= (on ENST00000468789 / NM_001105078.4; = p.C211= on NM_004991.4) | Silent (SNP) | VAF 111/239 reads (46%) | catalogued as rs188482846, COSV52976360; called by muse, mutect2, varscan2
- NR6A1 | c.51G>A p.S17= | Silent (SNP) | VAF 267/484 reads (55%) | called by muse, mutect2, varscan2
- PCDHA13 | c.1038C>T p.N346= | Silent (SNP) | VAF 115/279 reads (41%) | called by muse, mutect2, varscan2
- PCDHGB1 | c.1728C>T p.R576= | Silent (SNP) | VAF 149/371 reads (40%) | called by muse, mutect2, varscan2
- PPP1R17 | c.426C>T p.I142= | Silent (SNP) | VAF 264/580 reads (46%) | catalogued as rs961740202, COSV59611105; called by muse, mutect2, varscan2
- PRKX | c.109C>T p.L37= | Silent (SNP) | VAF 740/741 reads (100%) | called by muse, mutect2, varscan2
- RAB11FIP5 | c.507G>A p.T169= | Silent (SNP) | VAF 174/346 reads (50%) | catalogued as rs754181912, COSV99242569; called by muse, mutect2, varscan2
- SLC5A9 | c.702C>T p.D234= | Silent (SNP) | VAF 199/378 reads (53%) | catalogued as rs767631035, COSV52585979; called by muse, mutect2, varscan2
- SNX20 | c.684G>A p.P228= | Silent (SNP) | VAF 367/718 reads (51%) | catalogued as rs576966789; called by muse, mutect2, varscan2
- SNX32 | c.102G>A p.V34= | Silent (SNP) | VAF 408/409 reads (100%) | called by muse, mutect2, varscan2
- TRAV38-2DV8 | c.279A>G p.K93= | Silent (SNP) | VAF 154/519 reads (30%) | catalogued as rs747845669; called by muse, mutect2, varscan2
- UNCX | c.720C>T p.G240= | Silent (SNP) | VAF 131/326 reads (40%) | catalogued as COSV100310284; called by muse, mutect2, varscan2
- ZC3H11B | c.1525C>T p.L509= | Silent (SNP) | VAF 150/673 reads (22%) | called by muse, mutect2, varscan2
- CTBP2 | c.58+12848G>A | Intron (SNP) | VAF 264/531 reads (50%) | catalogued as rs200607400, COSV100456379; called by muse, mutect2, varscan2
- ERCC3 | c.1343-280C>T | Intron (SNP) | VAF 107/264 reads (41%) | catalogued as rs980941148; called by muse, mutect2, varscan2
- SLC4A11 | chr20:3238024 T>C | 5'Flank (SNP) | VAF 169/533 reads (32%) | called by muse, mutect2, varscan2
- TMTC3 | c.*2692G>A | 3'UTR (SNP) | VAF 60/255 reads (24%) | called by muse, mutect2, varscan2
- Z99774.2 | chr22:26675933 T>C | 3'Flank (SNP) | VAF 162/477 reads (34%) | called by muse, mutect2, varscan2
